Surgical pathology report (de-identified scan), TCGA case TCGA-MU-A51Y, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Minnesota, specimen TCGA-MU-A51Y-01A (Primary Tumor).

[page 1 of 7]
ORIGINAL REPORT:

SPECIMEN(S):

A: Specimen pending

B: Right pelvic lymph node

C: Left lymph nodes, pelvic

D: Left pelvic lymph node

E: Uterus, cervix, bilateral tubes, ovaries and upper vagina

ICD-0-3

Carcinoma, squamous cell, non-keratinizing, NOS
8072/3

Site: cervix, NOS C53.9

hw

10/4/12

FINAL DIAGNOSIS:

A. Lymph nodes, right pelvic, lymph node dissection:

- No evidence of malignancy in 11 lymph nodes (0/11).

B. Lymph nodes, right pelvic, lymph node dissection (including BFS1):

- Two lymph nodes with no evidence of malignancy (0/2).

C. Lymph nodes, left pelvic, lymph node dissection:

- No evidence of malignancy in 12 dissected lymph nodes (0/12).

D. Lymph nodes, left pelvic, lymph node dissection (including DFS1):

- No evidence of malignancy in two lymph nodes (0/2).

hw
10/4/12

[page 2 of 7]
E. Uterus, cervix, bilateral fallopian tubes and upper vagina,
hysterectomy, salpingectomy:

- Cervix with invasive, moderately differentiated squamous cell carcinoma, with papillary features.
- Extending into periuterine soft tissue.
- Invasive 1.8 of 2.1 cm thick resection.
- Associated with lymphovascular space invasion.
- Peripheral and vaginal margins of resection free of malignancy.
- Vaginal cuff with no histologic abnormality.
- Endometrium with proliferative pattern.
- Myometrium with adenomyosis.
- Right and left fallopian tubes with no histologic abnormality.

COMMENT:

Case Summary

Specimen: Cervix, uterine corpus, right fallopian tube: left fallopian tube

Procedure: Radical hysterectomy

Tumor Size: Greatest dimension: 2.3 cm, additional dimensions: 2.3 x 1.8 cm

Histologic Type Squamous cell carcinoma, nonkeratinizing

Histologic Grade: G2: Moderately differentiated

Margins: Margins uninvolved by invasive carcinoma

[page 3 of 7]
Lymph-Vascular Invasion: Present

Pathologic Staging pT2a N0

Primary Tumor (pT): pT2a1 [IIA1]: Clinically visible lesion d4.0 cm
in greatest dimension

Regional Lymph Nodes (pN): : No regional lymph node metastasis

Number of Lymph Nodes Examined: 27

Number of Lymph Nodes Involved: 0

Distant Metastasis (pM): Not applicable

I have personally reviewed all specimens and or slides, including the
listed special stains, and used them with my medical judgement to
determine the final diagnosis.

CLINICAL HISTORY:

The patient is a year-old woman with invasive squamous cell carcinoma
of the cervix. Operative Procedure: Radical
hysterectomy with bilateral salpingectomy.

GROSS:

A. The first container is additionally labeled "right pelvic lymph
node" and consists of three fragments of tan-yellow fibroadipose tissue
which measure in aggregate 4.5 x 3.7 x 2.0 cm. Eleven potential lymph
nodes ranging in size from 0.2 up to 1.3 cm in greatest dimension are
identified. All lymph nodes are submitted intact.

[page 4 of 7]
Summary of Sections:

A1 - three potential lymph nodes intact.

A2 - four potential lymph nodes intact.

A3 - four potential lymph nodes intact.

B. The second container is additionally labeled "right pelvic lymph node" and is received fresh for frozen section analysis. The specimen consists of a red-tan fragment of fibroadipose tissue which measures 2.0 x 1.7 x 0.4 cm. Two lymph nodes are identified within the specimen. All tissue is submitted for frozen section diagnosis BFS1. The frozen section remnant is submitted in the identically labeled cassette.

C. The third container is additionally labeled "left pelvic lymph nodes" and consists of two fragments of tan-yellow fibroadipose tissue which measure in aggregate 5.3 x 4.8 x 1.2 cm. The specimen is dissected revealing 12 potential lymph nodes ranging in size from 0.3 to 1.7 cm in greatest dimension.

Summary of Sections:

C1 - one bisected lymph node (inked black), and two intact lymph nodes.

C2 - one bisected lymph node (inked black), and two intact lymph nodes.

C3 - six lymph nodes, intact.

D. The next container is additionally labeled "left pelvic lymph nodes"

[page 5 of 7]
and is received fresh for frozen section diagnosis. The specimen consists of a 1.3 x 1.2 x 0.3 cm aggregate of fibroadipose tissue in which two lymph nodes are identified. Entire specimen is submitted for frozen section diagnosis as D1FS. The frozen section remnant is submitted in identically labeled cassette.

E. The next container is additionally labeled "uterus, cervix, bilateral fallopian tubes and upper vagina and is received fresh for TPF. The specimen consists of a 100 gm radical hysterectomy specimen which measures 8.0 cm from fundus to cervix x 2.7 cm from anterior to posterior x 3.2 cm from cornua to cornua. The specimen includes an associated vaginal cuff, which measures 0.8 cm on the anterior aspect of the specimen and 1.9 cm on the posterior aspect of the specimen. The right fallopian tube measures 6.7 x 0.5 cm and the left fallopian tube measures 6.1 x 0.6 cm. There is associated right parametrial tissue which measures 2.7 x 2.2 x 0.7 cm and left parametrial tissue which measures 3.1 x 2.1 x 0.8 cm. The vaginal cuff margin has been inked blue, and the cervical and lower uterine soft tissue resection margins have been inked black.

The specimen is bivalved revealing a cervical mass which measures 2.9 x 2.3 x 1.4 cm and involves approximately 80 percent of the circumference of the cervix. At the greatest depth of invasion, the tumor is 1.4 cm deep in a cross-section that measures 2.3 cm to the nearest inked resection margin. The cervical mass expands and then infiltrates

[page 6 of 7]
towards the lower uterine segment. The remainder of the endometrium is golden tan in color and without additional masses or lesions. The myometrium is tan-pink and exhibits a normal whorled appearance without identifiable lesions. The average endometrial thickness is 0.2 cm and the average myometrial thickness is 1.4 cm.

The right fallopian tube has a uniform caliber on cross-section, and one potential paratubal cyst is identified. Cross-sections of the left fallopian tube reveal a normal caliber throughout without identified masses or lesions.

The external surfaces of the uterus are smooth, glistening, tan-pink in color, and intact. Dissection of the right and left parametria reveal no discrete masses or lesions. Serial sections through the superior portion of the endomyometrium reveal no masses or lesions.

Representative tissue was procured for potential future studies from specimen E.

Summary of Sections:

E1 - representative right fallopian tube.

E2 - representative left fallopian tube.

E3 - right parametrial margin, en face.

E4 - left parametrial margin, en face.

E5 - anterior endomyometrium, full thickness.

[page 7 of 7]
E6 - posterior endomyometrium, full thickness.

E7-E9 - tumor, representative full thickness.

E10 - anterior lower uterine segment with potential tumor, 2 fragments.

E11 - posterior lower uterine segment to potential tumor, 1 fragment.

E12 - remainder of anterior vaginal cuff margin, en face.

E13 - remainder of posterior vaginal cuff margin, en face.

INTRAOPERATIVE CONSULTATION:

BFS Lymph node, right pelvic, excision:

- Negative for carcinoma (0/2)

DFS Lymph node, left pelvic, lymph node dissection:

- Negative for carcinoma (0/2)

MICROSCOPIC:

Sections of the cervix show moderately differentiated invasive squamous cell carcinoma. In some areas, the surface of the cervix demonstrates a papillary pattern. The tumor invades focally beyond the thick-walled vessels of the uterine vascular plexus, indicative of minimal and focal extrauterine extension. Lymphovascular space invasion is identified. Definitive perineural invasion is not present. The tumor invades 1.8 cm of a 2.1 cm thick uterine resection. The remainder of the lower uterine segment, endometrium, and myometrium are unremarkable. Permanent sections confirm the frozen section diagnosis.

Source: NCI Genomic Data Commons file 951573da-981c-4752-95e0-a389513e9ade (TCGA-MU-A51Y.6E5C4ACB-C01C-4AE3-B060-E354CFEF08A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).